Somatic mutation profile of tumor specimen TCGA-D3-A51N-06A (aliquot TCGA-D3-A51N-06A-11D-A25O-08) from TCGA case TCGA-D3-A51N, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.4 years (20,595 days).
Specimen TCGA-D3-A51N-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d193e19a-bcf4-4c42-a4ea-8c224816167a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A51N-10A (Blood Derived Normal), aliquot TCGA-D3-A51N-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de2855be-2eda-425c-bb77-1196811e87a9

The open-access MAF lists 103 somatic variants for this specimen: 74 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 27, Nonsense Mutation 5, RNA 1, Splice Site 1, Intron 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACSM2A | c.295G>A p.G99R (on ENST00000219054; = p.G20R on NM_001308169.2) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV54582700; called by muse, mutect2, varscan2
- ADAMTS5 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53176287, COSV53181881; called by muse, mutect2, varscan2
- APBA2 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV68789154; called by muse, mutect2, varscan2
- APCS | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as COSV54817436, COSV54818546; called by muse, mutect2, varscan2
- ARAP2 | c.4429A>G p.S1477G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV58283288; called by muse, mutect2
- ATG7 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.035); catalogued as COSV61611308, COSV61613839; called by muse, mutect2
- ATP5PD | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as COSV56902451; called by muse, mutect2, varscan2
- C1QTNF9 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV59656534; called by muse, mutect2, varscan2
- CDYL | c.1136T>C p.L379P (on ENST00000328908 / NM_001368125.1; = p.L325P on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59358426; called by mutect2, varscan2
- CNTNAP2 | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as COSV62149920; called by muse, mutect2, varscan2
- CUX1 | c.293G>A p.G98E (on ENST00000292535 / NM_181552.4; = p.G109E on NM_001913.5) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV52892427; called by muse, mutect2, varscan2
- CXADR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV53027998; called by muse, mutect2, varscan2
- DISP3 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53821633; called by muse, mutect2, varscan2
- DNAH9 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); catalogued as COSV52337009; called by muse, mutect2, varscan2
- DNMT3B | c.2060G>A p.G687D | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs559662934, COSV52415494; called by muse, mutect2, varscan2
- DSCAM | c.5926G>A p.G1976R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.844); catalogued as rs781586965, COSV68021899; called by muse, mutect2, varscan2
- DZIP3 | c.2260C>T p.Q754* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100848072, COSV64311272; called by muse, mutect2, varscan2
- EIF3H | c.829-1G>T p.X277_splice | Splice Site (SNP) | VAF 39/146 reads (27%) | catalogued as COSV52664431; called by muse, mutect2, varscan2
- ENPP4 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58088340; called by muse, mutect2, varscan2
- FANCE | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57689244; called by muse, mutect2, varscan2
- FAT3 | c.10804G>A p.D3602N | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs759869197, COSV53081631; called by muse, mutect2, varscan2
- FBN2 | c.7542G>C p.Q2514H | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.979); catalogued as COSV52496063; called by muse, mutect2, varscan2
- FRG1 | c.241G>C p.G81R | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV56996833; called by muse, mutect2
- FZD8 | c.105C>G p.C35W | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65967568; called by muse, mutect2, varscan2
- GALNT10 | c.1301G>C p.S434T | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51721417; called by muse, mutect2, varscan2
- GCN1 | c.3238G>A p.E1080K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.459); catalogued as COSV56104497; called by muse, mutect2, varscan2
- GK | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV66734084; called by muse, mutect2, varscan2
- HBE1 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV53079627; called by muse, mutect2, varscan2
- IL7R | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV57406297, COSV57407283; called by muse, mutect2, varscan2
- INSRR | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV63871212, COSV63874751; called by muse, mutect2, varscan2
- KBTBD13 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs568675071, COSV71351360; ClinVar: uncertain significance; called by muse, mutect2
- LAMA3 | c.4358G>A p.C1453Y | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58063398; called by muse, mutect2
- MAP3K13 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53984292; called by muse, mutect2, varscan2
- MGAT4C | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100152907, COSV59830417; called by muse, mutect2, varscan2
- MICB | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV52855580; called by muse, mutect2, varscan2
- MIIP | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV52427085; called by muse, mutect2, varscan2
- MORC1 | c.2915G>A p.R972K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.005); catalogued as COSV51715206, COSV99227890; called by muse, mutect2, varscan2
- MROH7 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV59868051; called by muse, mutect2, varscan2
- MSTO1 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55471419; called by muse, mutect2, varscan2
- MTOR | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as COSV63868914; called by muse, mutect2, varscan2
- MUC17 | c.7304G>T p.S2435I | Missense Mutation (SNP) | VAF 84/436 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV60281608; called by muse, mutect2, varscan2
- MYH2 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs763292061, COSV55432650; called by muse, mutect2, varscan2
- MYH8 | c.3449G>A p.S1150N | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV67960738; called by muse, mutect2, varscan2
- MYO9A | c.5488C>T p.P1830S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV61848123; called by muse, mutect2, varscan2
- NBEA | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1190989650, COSV59763269; called by muse, mutect2, varscan2
- NRAP | c.1304T>C p.V435A (on ENST00000359988 / NM_001322945.2; = p.V400A on NM_006175.4) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV63488812; called by muse, mutect2, varscan2
- OBSCN | c.11678G>A p.R3893Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs775176076, COSV52746847, COSV99476656; called by muse, mutect2, varscan2
- OR13D1 | c.869T>G p.M290R | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV59513553; called by muse, mutect2, varscan2
- OR52E6 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.655); catalogued as COSV61431454; called by muse, mutect2, varscan2
- PDC | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.655); catalogued as rs141620121, COSV60853972; called by muse, mutect2, varscan2
- PTGER3 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs754390775, COSV60688334, COSV60693133; called by muse, mutect2, varscan2
- RYR1 | c.6154G>A p.E2052K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as rs1343240354, COSV62090745; called by muse, mutect2, varscan2
- SEMA3E | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.42); PolyPhen probably damaging (1); catalogued as rs748042802, COSV57081175; called by muse, mutect2, varscan2
- SHROOM2 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV66604988; called by muse, mutect2, varscan2
- SKIL | c.1820T>A p.L607* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV52058505; called by muse, mutect2, varscan2
- SLC5A4 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56668814; called by muse, mutect2, varscan2
- SLC6A17 | c.1949C>T p.T650I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV58991631; called by muse, mutect2
- SNRK | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56066277; called by muse, mutect2, varscan2
- SREK1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV52331929; called by muse, mutect2, varscan2
- STUB1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV50196501; called by muse, mutect2, varscan2
- SYT2 | c.873C>G p.I291M | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100937132, COSV66141327; called by muse, varscan2
- TENM1 | c.3796C>T p.L1266F | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV64426134; called by muse, mutect2, varscan2
- TMPRSS15 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53035589; called by muse, mutect2, varscan2
- TNS4 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.691); catalogued as COSV54183607; called by muse, mutect2, varscan2
- TOB2 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV100548385, COSV59500456; called by muse, mutect2, varscan2
- TRIM71 | c.1530T>G p.Y510* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV67470250; called by muse, mutect2, varscan2
- TSHZ1 | c.226T>A p.S76T (on ENST00000580243 / NM_001308210.2; = p.S31T on NM_005786.6) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100433560; called by muse, mutect2, varscan2
- TTC16 | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs762845145, COSV58852175; called by muse, mutect2, varscan2
- UGT2B15 | c.1014G>A p.W338* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | catalogued as rs773027308, COSV57732870; called by muse, mutect2, varscan2
- ZNF534 | c.598G>A p.G200R (on ENST00000332323 / NM_001143939.3; = p.G187R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV56514850; called by muse, mutect2, varscan2
- ZNF622 | c.856T>A p.S286T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.76); catalogued as COSV58073597; called by muse, mutect2, varscan2
- DUSP6 | c.76dup p.Q26Pfs*45 | Frame Shift Ins (INS) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- TOP1 | c.715_716del p.K239Vfs*4 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- CACNA1H | c.6474G>A p.A2158= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs747394862, COSV52352998; called by muse, mutect2, varscan2
- CC2D2B | c.588C>A p.G196= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV60357318; called by muse, mutect2, varscan2
- HAPLN3 | c.153G>A p.V51= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV62084483; called by muse, mutect2, varscan2
- IDH3G | c.435C>T p.V145= | Silent (SNP) | VAF 7/137 reads (5%) | catalogued as COSV54206306; called by muse, mutect2
- KEL | c.156C>T p.I52= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV62333589; called by muse, mutect2
- LAMA3 | c.3468C>T p.S1156= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV58063392; called by muse, varscan2
- LGSN | c.882G>A p.R294= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV65726364; called by muse, mutect2, varscan2
- MARK2 | c.384C>A p.V128= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV59281013; called by muse, mutect2, varscan2
- NELL1 | c.621G>A p.G207= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV54242700; called by muse, mutect2, varscan2
- NLRP11 | c.81G>A p.K27= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs753666116, COSV64085942; called by muse, mutect2, varscan2
- NOL4 | c.1311C>T p.I437= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV52340484; called by muse, mutect2, varscan2
- OR4B1 | c.483C>T p.I161= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as rs755470435, COSV58882112; called by muse, mutect2, varscan2
- OR51F1 | c.717C>T p.S239= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV58578993; called by muse, mutect2
- OR52M1 | c.546T>C p.C182= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs996111683, COSV64171539; called by muse, mutect2, varscan2
- OR5I1 | c.192C>T p.F64= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV56885704; called by muse, mutect2, varscan2
- OR8K3 | c.486G>A p.K162= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs533366100, COSV57130906; called by muse, mutect2, varscan2
- PCDHAC2 | c.1311C>T p.I437= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV53838876; called by muse, mutect2, varscan2
- PCDHGB6 | c.1272C>T p.A424= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV53907530; called by muse, mutect2, varscan2
- PGAM4 | c.651C>T p.V217= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV58443315; called by muse, mutect2, varscan2
- PLEC | c.11869C>T p.L3957= (on ENST00000322810 / NM_201380.4; = p.L3847= on NM_000445.5) | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1554674991, COSV59608324; called by muse, mutect2, varscan2
- PNMA3 | c.987C>T p.L329= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV64721844, COSV64722847; called by muse, mutect2, varscan2
- POLR2J3 | c.87C>T p.A29= | Silent (SNP) | VAF 22/222 reads (10%) | called by mutect2, varscan2
- RRM2B | c.225C>T p.L75= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV52565854; called by muse, mutect2, varscan2
- SLC36A2 | c.420G>A p.Q140= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV58862268, COSV58864849; called by muse, mutect2, varscan2
- SOGA1 | c.2205C>T p.L735= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as rs750353187, COSV52912672; called by muse, mutect2, varscan2
- STXBP5L | c.390T>C p.S130= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as COSV56502232, COSV56514489; called by muse, mutect2, varscan2
- TSHZ1 | c.225G>A p.G75= (on ENST00000580243 / NM_001308210.2; = p.G30= on NM_005786.6) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100433558; called by muse, mutect2, varscan2
- AC244258.1 | n.974G>A | RNA (SNP) | VAF 32/117 reads (27%) | catalogued as rs536855519; called by muse, mutect2, varscan2
- CTBP2 | c.58+12846C>T | Intron (SNP) | VAF 42/92 reads (46%) | catalogued as COSV58343338; called by muse, mutect2
